Somatic mutation profile of tumor specimen 0DLDZN from CCDI case PBBZAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Pharynx, NOS; Age at diagnosis: 4.7 years (1,702 days).
Specimen 0DLDZN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d6e5fbc-8993-4bb5-ab65-44719991dcac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLDZA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b708191-850c-4661-989b-87cf3b538e0b

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, 3'UTR 4, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBX1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 356/1069 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.808); catalogued as rs765062326; called by muse, mutect2, varscan2
- CHD8 | c.1423C>T p.R475C (on ENST00000646647 / NM_001170629.2; = p.R196C on NM_020920.4) | Missense Mutation (SNP) | VAF 385/1662 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1447949003, COSV67872848; called by muse, mutect2, varscan2
- EPHA6 | c.2227C>T p.R743C (on ENST00000389672 / NM_001080448.3; = p.R135C on NM_173655.4) | Missense Mutation (SNP) | VAF 211/750 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs747936940, COSV67591172; called by muse, mutect2, varscan2
- ESRRB | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 265/1077 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.062); catalogued as rs773933130; called by muse, mutect2, varscan2
- IGF2R | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 421/1373 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs375243560; called by muse, mutect2, varscan2
- PCDHA10 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV100252212, COSV56491089; called by muse, mutect2
- SLC8A2 | c.1782G>T p.K594N | Missense Mutation (SNP) | VAF 354/1375 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.295); catalogued as COSV52641299, COSV99370182; called by muse, mutect2, varscan2
- SPPL2C | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 227/669 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.216); catalogued as rs1407455788; called by muse, mutect2, varscan2
- TAAR8 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 324/867 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV51587050; called by mutect2, varscan2
- TRPS1 | c.3821A>G p.E1274G (on ENST00000220888 / NM_001330599.2; = p.E1287G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 586/1925 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV55237071; called by muse, mutect2, varscan2
- UCP3 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 274/1245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775441399; called by muse, mutect2, varscan2
- ZC2HC1C | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 299/1335 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs184717760, COSV99472926; called by muse, mutect2, varscan2
- ANKRD36B | c.1111A>G p.K371E | Missense Mutation (SNP) | VAF 549/2449 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATCAY | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 340/1301 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMSAP3 | c.1036A>T p.N346Y | Missense Mutation (SNP) | VAF 155/612 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CHRNA9 | c.596A>C p.E199A | Missense Mutation (SNP) | VAF 106/1102 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.479); called by muse, mutect2
- CLSTN3 | c.1863G>T p.E621D | Missense Mutation (SNP) | VAF 196/936 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EHD3 | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 164/695 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FOXP4 | c.1618G>A p.E540K (on ENST00000307972 / NM_001012426.1; = p.E527K on NM_138457.3) | Missense Mutation (SNP) | VAF 378/1086 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GOLGA1 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 207/391 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP1B | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 286/1686 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPK8IP1 | c.523-5C>A | Splice Region (SNP) | VAF 54/594 reads (9%) | called by muse, mutect2
- NF1 | c.2536G>C p.A846P | Missense Mutation (SNP) | VAF 231/700 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC39A6 | c.2115+4A>C | Splice Region (SNP) | VAF 146/461 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.16934G>A p.S5645N (on ENST00000591111; = p.S4718N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/973 reads (7%) | PolyPhen benign (0.124); called by muse, mutect2
- VPS13B | c.929A>T p.N310I | Missense Mutation (SNP) | VAF 188/1184 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- YBEY | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 197/601 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- COL14A1 | c.882G>T p.V294= | Silent (SNP) | VAF 222/1504 reads (15%) | catalogued as COSV52847420, COSV52862904; called by mutect2, varscan2
- MAPK8IP3 | c.3663C>G p.P1221= | Silent (SNP) | VAF 129/348 reads (37%) | called by muse, mutect2, varscan2
- NPAP1 | c.522C>T p.D174= | Silent (SNP) | VAF 219/693 reads (32%) | catalogued as rs368120585, COSV100274980; called by muse, mutect2, varscan2
- PLEKHH1 | c.79C>A p.R27= | Silent (SNP) | VAF 225/971 reads (23%) | catalogued as COSV100232660; called by muse, mutect2, varscan2
- TGIF2LY | c.198C>T p.R66= | Silent (SNP) | VAF 343/681 reads (50%) | catalogued as COSV100339704; called by muse, mutect2, varscan2
- TWIST1 | c.501G>A p.E167= | Silent (SNP) | VAF 129/376 reads (34%) | catalogued as COSV99643032; called by muse, mutect2, varscan2
- ITPK1 | c.*3064T>A | 3'UTR (SNP) | VAF 262/1100 reads (24%) | called by muse, mutect2, varscan2
- MTDH | c.*24T>A | 3'UTR (SNP) | VAF 56/2134 reads (3%) | called by muse, mutect2
- PARP12 | c.-30C>T | 5'UTR (SNP) | VAF 74/162 reads (46%) | catalogued as rs1052986134; called by muse, mutect2, varscan2
- PHF3 | c.*8142A>C | 3'UTR (SNP) | VAF 28/436 reads (6%) | called by muse, mutect2
- ZNF750 | c.*29C>A | 3'UTR (SNP) | VAF 86/184 reads (47%) | called by muse, mutect2, varscan2
